Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A23U, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A23U-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD-0-3

Dedifferentiated liposarcoma 8858/3
Site: (Other) Groin, soft tissue c 49.5

hr 4/21/11

....

Clinical Diagnosis & History:
Groin sarcoma.

Specimens Submitted:
1: SP: Tru-cut bx to left groin
2: SP: Sarcoma, right groin
3: SP: Left groin sarcoma
4: SP: Left groin dissection

DIAGNOSIS:

- 1) SOFT TISSUE, LEFT GROIN; TRU-CUT BIOPSY:
- HIGH GRADE SPINDLE CELL SARCOMA.
- 2) SOFT TISSUE, RIGHT GROIN TUMOR; EXCISION:
- HIGH GRADE SPINDLE CELL SARCOMA CONSISTENT WITH DEDIFFERENTIATED LIPOSARCOMA, ARISING IN WELL DIFFERENTIATED SCLEROSING LIPOSARCOMA INVOLVING SUBCUTANEOUS TISSUE AND SKELETAL MUSCLE.
- TUMOR MEASURES 8.0 CM IN LARGEST DIMENSION.
- TUMOR EXTENDS TO MARGIN OF RESECTION.
- SKIN WITH SCAR.
- 3) SOFT TISSUE, LEFT GROIN MASS; EXCISION:
- DEDIFFERENTIATED LIPOSARCOMA ARISING IN A WELL-DIFFERENTIATED SCLEROSING LIPOSARCOMA INVOLVING SUBCUTANEOUS TISSUE.
- TUMOR MEASURES 12 CM IN LARGEST DIMENSION AND EXTENDS TO THE MARGIN OF RESECTION.
- 4) LYMPH NODES, LEFT GROIN; DISSECTION:
- LOW GRADE WELL-DIFFERENTIATED SCLEROSING AND LIPOMA-LIKE LIPOSARCOMA ENCASING LYMPH NODES.
- NINETEEN BENIGN LYMPH NODES (0/19).
- SKIN WITH SCAR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED

PATH
REPORT

** Continued on next page **

[page 2 of 4]
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:	Special Stain	Comment
Result	SMA	
POSITIVE	CMA (HHF35)	
POSITIVE	des	
POSITIVE	AE1:AE3	
NEGATIVE	CAM 5.2	
NEGATIVE	KP1 (CD68)	
POSITIVE	MUCIN	
NEGATIVE	CK7	
NEGATIVE	CK20	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	
	NEG CONT	

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Tru-cut biopsy to left groin". It consists of a core biopsy of tan soft tissue measuring 1.3 x 0.2 x 0.2 cm. Entirely frozen.

Summary of sections:

FSC - frozen section control

2) The specimen is received fresh, labeled "Sarcoma right groin". It consists of a fragment of soft tissue, received unoriented, measuring 11 x 6 x 3.5 cm covered by an ellipse of white wrinkled skin measuring 5.5 x 2 cm showing two old healed scars measuring 2 cm each. The specimen is inked black and bisected. The cut surface reveals multinodular ill-defined mass approaching the margin of resection and measuring approximately 8 x 6 x 2.5 cm, present in the subcutaneous tissue. The mass has a rubbery tan-yellow cut surface. Representative sections are submitted. A portion is submitted for

Summary of sections:

TS tumor to skin

T - tumor

3) The specimen is received fresh, labeled "Left groin sarcoma". It consists of a fragment of soft tissue, received unoriented, measuring 12 x 9 x 6 cm covered by a skeletal muscle measuring approximately 9 x 7 x 0.5 cm. The specimen is inked and serially sectioned. The cut section reveal multinodular tan-yellow, homogenous. There is no area of necrosis or hemorrhage identified. The tumor appears to be entirely surrounded by

PATH
REPORT

** Continued on next page **

[page 3 of 4]
Page 3 of 4
capsule, skeletal muscle and fibroadipose tissue. Representative sections
are submitted. A portion is submitted for

Summary of sections:
T - tumor

4) The specimen is received in formalin, labeled "Left Groin
Dissection". It consists of a portion of fibroadipose tissue measuring 14 x
7 x 2 cm, covered by an ellipse of skin measuring 7 x 0.5 cm and a portion
of skeletal muscle measuring 5.5 x 2 x 0.2 cm. Multiple lymph nodes are
identified measuring from 0.5 to 2 cm. Entirely submitted.

Summary of Sections:
S skin
BLN bisected lymph node
HLN half lymph node
LN - lymph nodes

Summary of Sections:
Part 1: SP: Tru-cut bx to left groin

Block	Sect.	Site	PCs
1		FSC	1

Part 2: SP: Sarcoma, right groin

Block	Sect.	Site	PCs
7		T	7
2		TS	2

Part 3: SP: Left groin sarcoma

Block	Sect.	Site	PCs
8		T	8

Part 4: SP: Left groin dissection

Block	Sect.	Site	PCs
1		BLN	1
4		HLN	4
16		LN	16
1		S	1

Intraoperative Consultation:

PATH
REPORT

** Continued on next page **

[page 4 of 4]
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SPINDLE CELL SARCOMA, A BIT MORE
PLEOMORPHIC THAN THE OTHER SIDE
PERMANENT DIAGNOSIS: SAME.

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file 34f327ca-fa9f-4339-96ac-2c0bde15a143 (TCGA-DX-A23U.1AE1CF17-2789-4FBB-8226-8855BC02C659.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).